Somatic mutation profile of tumor specimen MMRF_1974_1_BM_CD138pos (aliquot MMRF_1974_1_BM_CD138pos_T1_KBS5U_L07297) from MMRF case MMRF_1974, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.3 years (22,028 days).
Specimen MMRF_1974_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 81c1bf20-489e-4905-8508-296ff51f57af.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1974_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1974_1_PB_Whole_C3_KBS5U_L07291; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92e48161-1158-4511-88cc-116638110ddf

The open-access MAF lists 171 somatic variants for this specimen: 73 protein-altering or splice-affecting, 24 silent, 74 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 60, 3'UTR 40, Silent 24, Intron 19, Nonsense Mutation 6, 5'UTR 5, 3'Flank 4, Splice Region 3, 5'Flank 3, RNA 3, Frame Shift Del 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS4 | c.2119G>A p.A707T | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.327); catalogued as rs768584236, COSV63491126; called by muse, mutect2, varscan2
- ASB17 | c.772C>T p.H258Y | Missense Mutation (SNP) | VAF 15/114 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs751185872; called by muse, mutect2, varscan2
- CHD2 | c.1861C>T p.R621W | Missense Mutation (SNP) | VAF 22/96 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064795815, COSV67709557; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DHX34 | c.346C>T p.R116W | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs369824141; called by muse, mutect2, varscan2
- DSCAM | c.2434C>T p.H812Y | Missense Mutation (SNP) | VAF 24/127 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.184); catalogued as COSV101260071; called by muse, mutect2, varscan2
- ELF2 | c.353-5T>A | Splice Region (SNP) | VAF 27/104 reads (26%) | catalogued as rs1333839030, COSV55494708; called by muse, mutect2, varscan2
- FAM20A | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as rs770194120; called by muse, mutect2, varscan2
- IGLV4-69 | c.63G>C p.Q21H | Missense Mutation (SNP) | VAF 116/234 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as rs372152625; called by muse, varscan2
- LRATD1 | c.689G>T p.G230V | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1312212476; called by muse, mutect2, varscan2
- MAX | c.2T>G p.M1? | Translation Start Site (SNP) | VAF 7/91 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as CM122944; called by muse, mutect2
- MRNIP | c.634G>A p.G212R | Missense Mutation (SNP) | VAF 65/205 reads (32%) | SIFT tolerated (0.92); PolyPhen benign (0.013); catalogued as rs1489694869; called by muse, mutect2, varscan2
- PRKCQ | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 26/131 reads (20%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.83); catalogued as COSV54113548; called by muse, mutect2, varscan2
- RFX2 | c.1393C>T p.P465S | Missense Mutation (SNP) | VAF 14/105 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.78); catalogued as rs1233964758; called by muse, mutect2, varscan2
- TACC2 | c.310C>T p.R104* | Nonsense Mutation (SNP) | VAF 20/142 reads (14%) | catalogued as rs377057058; called by muse, mutect2, varscan2
- TMPRSS6 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 25/53 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201244227, COSV100695446; called by muse, mutect2, varscan2
- TRMT9B | c.840C>A p.S280R | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV71600341; called by muse, varscan2
- TRMT9B | c.1193C>T p.P398L | Missense Mutation (SNP) | VAF 52/217 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as rs774595233; called by muse, varscan2
- ZFPM2 | c.2105A>G p.Y702C | Missense Mutation (SNP) | VAF 64/136 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV65875963; called by muse, mutect2, varscan2
- AC135068.1 | c.808G>A p.D270N | Missense Mutation (SNP) | VAF 67/150 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANO4 | c.8C>T p.S3F | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.582); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2889A>C p.R963S | Missense Mutation (SNP) | VAF 48/89 reads (54%) | SIFT tolerated, low confidence (0.73); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- BUD13 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CCNC | c.805G>C p.E269Q | Missense Mutation (SNP) | VAF 39/315 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CCR5 | c.263A>T p.H88L | Missense Mutation (SNP) | VAF 23/171 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- CD27 | c.193_194del p.C65Hfs*9 | Frame Shift Del (DEL) | VAF 39/148 reads (26%) | called by mutect2, pindel, varscan2
- CDK5RAP2 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEP295 | c.4867G>A p.E1623K | Missense Mutation (SNP) | VAF 16/298 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.17); called by muse, mutect2
- COL7A1 | c.6903T>C p.A2301= | Splice Region (SNP) | VAF 57/138 reads (41%) | called by muse, mutect2, varscan2
- CPXM1 | c.2200G>A p.D734N | Missense Mutation (SNP) | VAF 32/97 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRAMP1 | c.1108G>T p.E370* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | called by mutect2, varscan2
- DGCR8 | c.1890-8T>A | Splice Region (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2, varscan2
- DIS3 | c.2318C>T p.T773I | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- DST | c.250C>T p.R84* | Nonsense Mutation (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2
- E2F6 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ETNPPL | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 37/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- FUBP1 | c.910G>T p.D304Y | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- FUBP1 | c.694G>C p.D232H | Missense Mutation (SNP) | VAF 54/242 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, varscan2
- FUBP1 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 13/42 reads (31%) | called by muse, mutect2, varscan2
- FUBP1 | c.392G>T p.G131V | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FUBP1 | c.212-1G>T p.X71_splice | Splice Site (SNP) | VAF 15/48 reads (31%) | called by muse, mutect2, varscan2
- GSDMD | c.928C>T p.Q310* | Nonsense Mutation (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- HNRNPM | c.1431G>C p.E477D | Missense Mutation (SNP) | VAF 69/233 reads (30%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV4-69 | c.286T>G p.Y96D | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, varscan2
- IMPACT | c.497A>T p.E166V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- ITIH4 | c.1446C>A p.F482L | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KIF4A | c.2185A>G p.K729E | Missense Mutation (SNP) | VAF 76/85 reads (89%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- L3MBTL4 | c.1325G>A p.C442Y | Missense Mutation (SNP) | VAF 8/73 reads (11%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- MLANA | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 126/439 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- NRCAM | c.3158T>A p.I1053N | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- NRP2 | c.2766G>A p.M922I (on ENST00000360409 / NM_201266.2; = p.M917I on NM_003872.3) | Missense Mutation (SNP) | VAF 35/242 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- NUDT18 | c.673G>A p.E225K | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.068); called by muse, mutect2
- OLFM1 | c.5C>T p.S2L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PCDH15 | c.4706A>C p.K1569T | Missense Mutation (SNP) | VAF 70/142 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- PNISR | c.389A>T p.D130V | Missense Mutation (SNP) | VAF 54/128 reads (42%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RYR1 | c.11524del p.D3842Ifs*17 | Frame Shift Del (DEL) | VAF 32/148 reads (22%) | called by mutect2, varscan2
- SH3D19 | c.1933C>A p.L645M | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.24); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- SP3 | c.1921C>T p.H641Y | Missense Mutation (SNP) | VAF 22/101 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPEN | c.302G>C p.S101T | Missense Mutation (SNP) | VAF 8/163 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.867); called by muse, mutect2
- SPHKAP | c.1394C>A p.P465Q | Missense Mutation (SNP) | VAF 18/125 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- SWT1 | c.635C>G p.S212C | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- SYDE2 | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAOK3 | c.2110G>A p.E704K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.489); called by muse, mutect2, varscan2
- TENM1 | c.2662G>C p.V888L | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TMPRSS12 | c.970G>A p.G324S | Missense Mutation (SNP) | VAF 193/382 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TOPAZ1 | c.1229A>T p.H410L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- TRIOBP | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 29/204 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- TRMT9B | c.781C>G p.L261V | Missense Mutation (SNP) | VAF 30/166 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, varscan2
- TRMT9B | c.1192C>T p.P398S | Missense Mutation (SNP) | VAF 52/212 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, varscan2
- TRMT9B | c.1318C>A p.H440N | Missense Mutation (SNP) | VAF 58/262 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, varscan2
- TSPOAP1 | c.2116C>T p.R706* | Nonsense Mutation (SNP) | VAF 24/75 reads (32%) | called by muse, mutect2, varscan2
- YTHDC1 | c.1416G>T p.K472N (on ENST00000344157 / NM_001031732.4; = p.K454N on NM_133370.4) | Missense Mutation (SNP) | VAF 28/109 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZIM2 | c.668A>G p.D223G | Missense Mutation (SNP) | VAF 37/70 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- ZNF638 | c.1121A>G p.Q374R | Missense Mutation (SNP) | VAF 128/274 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.321); called by muse, mutect2, varscan2
- AGBL1 | c.2037C>T p.P679= | Silent (SNP) | VAF 25/92 reads (27%) | called by muse, mutect2, varscan2
- ANK3 | c.10401C>T p.I3467= | Silent (SNP) | VAF 29/96 reads (30%) | catalogued as rs200592890, COSV55058289; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK16 | c.1062G>A p.E354= | Silent (SNP) | VAF 19/75 reads (25%) | called by muse, mutect2, varscan2
- COL6A1 | c.609C>T p.I203= | Silent (SNP) | VAF 12/97 reads (12%) | catalogued as rs369590506; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- DENND2C | c.241C>T p.L81= | Silent (SNP) | VAF 84/151 reads (56%) | catalogued as COSV101283915; called by muse, mutect2, varscan2
- DLEC1 | c.4350T>C p.F1450= | Silent (SNP) | VAF 38/128 reads (30%) | called by muse, mutect2, varscan2
- GALR3 | c.897C>T p.R299= | Silent (SNP) | VAF 10/43 reads (23%) | catalogued as rs1283128322; called by muse, mutect2, varscan2
- GLDC | c.2925C>T p.F975= | Silent (SNP) | VAF 10/168 reads (6%) | catalogued as rs1052505781; ClinVar: uncertain significance; called by muse, mutect2
- IP6K1 | c.822C>T p.L274= | Silent (SNP) | VAF 31/121 reads (26%) | called by muse, mutect2, varscan2
- MDH1 | c.810T>A p.G270= | Silent (SNP) | VAF 20/214 reads (9%) | called by muse, mutect2
- MUC22 | c.198C>A p.T66= | Silent (SNP) | VAF 69/300 reads (23%) | called by muse, mutect2, varscan2
- OR10J1 | c.726C>A p.S242= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as COSV71128254; called by muse, mutect2
- OR5AS1 | c.99G>A p.L33= | Silent (SNP) | VAF 51/169 reads (30%) | catalogued as COSV57981067; called by muse, mutect2, varscan2
- PCDHGA4 | c.2370C>T p.L790= | Silent (SNP) | VAF 10/58 reads (17%) | catalogued as rs1209475845; called by muse, mutect2, varscan2
- PTAR1 | c.171G>A p.E57= | Silent (SNP) | VAF 42/314 reads (13%) | called by muse, mutect2, varscan2
- QSER1 | c.4890T>C p.A1630= (on ENST00000399302; = p.A1759= on NM_001076786.3) | Silent (SNP) | VAF 15/37 reads (41%) | called by muse, mutect2, varscan2
- RDH10 | c.828C>T p.A276= | Silent (SNP) | VAF 86/180 reads (48%) | called by muse, mutect2, varscan2
- SEPTIN1 | c.927C>T p.F309= (on ENST00000321367; = p.F262= on NM_052838.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 65/212 reads (31%) | called by muse, mutect2, varscan2
- SLC7A14 | c.2046C>T p.S682= | Silent (SNP) | VAF 3/46 reads (7%) | catalogued as rs1421324353, COSV51577800; called by muse, mutect2
- SUPV3L1 | c.2154T>C p.S718= | Silent (SNP) | VAF 24/136 reads (18%) | called by muse, mutect2, varscan2
- TMEM156 | c.174G>C p.V58= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV60744011; called by muse, mutect2, varscan2
- TNRC6B | c.2943C>T p.N981= (on ENST00000454349 / NM_001162501.2; = p.N234= on NM_001024843.1) | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs1240337931, COSV57309464; called by muse, mutect2, varscan2
- TULP3 | c.1002G>A p.Q334= | Silent (SNP) | VAF 17/71 reads (24%) | called by muse, mutect2, varscan2
- ZNF227 | c.2103G>A p.L701= | Silent (SNP) | VAF 40/129 reads (31%) | catalogued as COSV57314049; called by muse, mutect2, varscan2
- ADCY2 | c.*109G>A | 3'UTR (SNP) | VAF 18/179 reads (10%) | called by muse, mutect2, varscan2
- ADGRL2 | c.3625+397A>T | Intron (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- ADH7 | chr4:99435679 T>C | 5'Flank (SNP) | VAF 9/59 reads (15%) | called by muse, mutect2, varscan2
- AFAP1L2 | chr10:114404685 C>T | 5'Flank (SNP) | VAF 13/40 reads (33%) | called by muse, mutect2, varscan2
- AK2 | chr1:33008408 G>A | 3'Flank (SNP) | VAF 35/118 reads (30%) | called by muse, mutect2, varscan2
- ARHGEF26 | c.*969C>T | 3'UTR (SNP) | VAF 3/9 reads (33%) | called by muse, mutect2
- ARRDC4 | c.*2302G>A | 3'UTR (SNP) | VAF 23/131 reads (18%) | catalogued as rs1054554898; called by muse, mutect2, varscan2
- ATG5 | c.*2005A>G | 3'UTR (SNP) | VAF 28/74 reads (38%) | called by muse, mutect2, varscan2
- CACNA1H | c.803+20G>A | Intron (SNP) | VAF 26/88 reads (30%) | catalogued as rs777633784; called by muse, mutect2, varscan2
- CACNB4 | c.*1490T>A | 3'UTR (SNP) | VAF 10/139 reads (7%) | catalogued as rs1396555430, COSV52397389; called by muse, mutect2
- CACNG3 | c.*252C>A | 3'UTR (SNP) | VAF 48/180 reads (27%) | called by muse, mutect2, varscan2
- CADM3 | c.*1964C>T | 3'UTR (SNP) | VAF 48/108 reads (44%) | called by muse, mutect2, varscan2
- CBLN4 | c.-929C>T | 5'UTR (SNP) | VAF 32/163 reads (20%) | called by muse, mutect2, varscan2
- CCNL1 | chr3:157160250 C>G | 5'Flank (SNP) | VAF 10/65 reads (15%) | called by muse, mutect2, varscan2
- CDH7 | chr18:65884266 C>T | 3'Flank (SNP) | VAF 39/154 reads (25%) | called by muse, mutect2, varscan2
- DDX21 | c.*1393C>A | 3'UTR (SNP) | VAF 43/112 reads (38%) | called by muse, mutect2, varscan2
- DDX21 | c.*1394A>T | 3'UTR (SNP) | VAF 44/114 reads (39%) | called by muse, mutect2, varscan2
- DHX37 | c.2696-49T>A | Intron (SNP) | VAF 20/62 reads (32%) | called by muse, mutect2, varscan2
- EPHB2 | c.*885C>T | 3'UTR (SNP) | VAF 13/74 reads (18%) | called by muse, mutect2, varscan2
- ESR1 | c.*1305C>T | 3'UTR (SNP) | VAF 32/70 reads (46%) | called by muse, mutect2, varscan2
- ETNK1 | c.156+541G>A | Intron (SNP) | VAF 17/72 reads (24%) | called by muse, mutect2
- ETNK1 | c.*284G>C | 3'UTR (SNP) | VAF 4/86 reads (5%) | called by muse, mutect2
- EXT1 | c.*384C>T | 3'UTR (SNP) | VAF 20/129 reads (16%) | called by muse, mutect2, varscan2
- FSTL5 | c.*1848T>G | 3'UTR (SNP) | VAF 11/33 reads (33%) | called by muse, mutect2, varscan2
- FSTL5 | c.*1706del | 3'UTR (DEL) | VAF 24/77 reads (31%) | called by mutect2, pindel, varscan2
- FUS | c.765-23T>G | Intron (SNP) | VAF 41/108 reads (38%) | called by muse, mutect2, varscan2
- GATB | c.1007+505A>C | Intron (SNP) | VAF 14/49 reads (29%) | called by muse, mutect2
- GATM | c.70-233A>G | Intron (SNP) | VAF 13/113 reads (12%) | called by muse, mutect2
- GPT2 | c.*135G>A | 3'UTR (SNP) | VAF 13/52 reads (25%) | called by muse, mutect2, varscan2
- GSN-AS1 | n.800G>A | RNA (SNP) | VAF 44/129 reads (34%) | called by muse, mutect2, varscan2
- H2AJ | chr12:14777375 G>T | 3'Flank (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- HOXA7 | c.*293G>A | 3'UTR (SNP) | VAF 15/82 reads (18%) | catalogued as rs947290705; called by mutect2, varscan2
- HTR5A | c.-248G>A | 5'UTR (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- IFIT2 | c.*1497G>C | 3'UTR (SNP) | VAF 27/70 reads (39%) | called by muse, mutect2, varscan2
- ING5 | c.*561dup | 3'UTR (INS) | VAF 16/65 reads (25%) | called by mutect2, pindel, varscan2
- IRF2BP2 | c.*1012T>C | 3'UTR (SNP) | VAF 65/129 reads (50%) | called by muse, mutect2, varscan2
- LGR5 | c.-224G>A | 5'UTR (SNP) | VAF 3/32 reads (9%) | called by muse, mutect2
- LINC01148 | n.305A>G | RNA (SNP) | VAF 122/289 reads (42%) | called by muse, mutect2, varscan2
- LRP2BP | c.106+354A>C | Intron (SNP) | VAF 35/87 reads (40%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40546406 T>C | 3'Flank (SNP) | VAF 62/145 reads (43%) | catalogued as rs772581963; called by muse, mutect2, varscan2
- NCAPD3 | c.64+603C>T | Intron (SNP) | VAF 28/56 reads (50%) | called by muse, mutect2, varscan2
- NF1 | c.7739-10C>T | Intron (SNP) | VAF 27/105 reads (26%) | called by muse, mutect2, varscan2
- NMNAT2 | c.574+195C>G | Intron (SNP) | VAF 18/69 reads (26%) | called by mutect2, varscan2
- NMT2 | c.*374G>T | 3'UTR (SNP) | VAF 55/107 reads (51%) | called by muse, mutect2, varscan2
- NSD2 | c.1881+301G>T | Intron (SNP) | VAF 25/100 reads (25%) | called by muse, mutect2, varscan2
- NSD2 | c.1882-2772G>A | Intron (SNP) | VAF 8/161 reads (5%) | called by muse, mutect2
- OGFOD1 | c.300+1468T>A | Intron (SNP) | VAF 6/33 reads (18%) | called by muse, mutect2, varscan2
- OR9I1 | c.-17C>T | 5'UTR (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- PCDH18 | c.*1956A>G | 3'UTR (SNP) | VAF 20/100 reads (20%) | called by muse, mutect2, varscan2
- PGM2L1 | c.*615C>T | 3'UTR (SNP) | VAF 68/154 reads (44%) | called by muse, mutect2, varscan2
- PHLDB2 | c.*755del | 3'UTR (DEL) | VAF 36/72 reads (50%) | catalogued as rs914570563; called by mutect2, varscan2
- PIK3C3 | c.*1876A>G | 3'UTR (SNP) | VAF 34/70 reads (49%) | called by muse, mutect2, varscan2
- PKD1L2 | n.1174C>T | RNA (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2, varscan2
- POLA2 | c.744+57C>T | Intron (SNP) | VAF 33/97 reads (34%) | catalogued as rs559756908; called by muse, mutect2, varscan2
- PRKCI | c.*1976C>G | 3'UTR (SNP) | VAF 49/174 reads (28%) | called by muse, mutect2, varscan2
- PRKCI | c.*2299C>A | 3'UTR (SNP) | VAF 28/103 reads (27%) | called by muse, mutect2, varscan2
- QKI | c.*369G>A | 3'UTR (SNP) | VAF 39/148 reads (26%) | called by muse, mutect2, varscan2
- RBM27 | c.*2860A>T | 3'UTR (SNP) | VAF 48/109 reads (44%) | called by muse, mutect2, varscan2
- ROPN1 | c.116+275A>G | Intron (SNP) | VAF 20/219 reads (9%) | called by muse, mutect2
- ROR2 | c.*1024T>C | 3'UTR (SNP) | VAF 85/265 reads (32%) | called by muse, mutect2, varscan2
- SCGB2A2 | c.*129G>A | 3'UTR (SNP) | VAF 63/328 reads (19%) | catalogued as COSV57174903, COSV99929254; called by muse, mutect2, varscan2
- SIX6 | c.*923C>A | 3'UTR (SNP) | VAF 5/49 reads (10%) | called by muse, mutect2, varscan2
- SLC33A1 | c.*270A>C | 3'UTR (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- SLC35D1 | c.*4240G>A | 3'UTR (SNP) | VAF 14/38 reads (37%) | called by muse, mutect2
- SLC45A4 | c.242-6539G>A | Intron (SNP) | VAF 25/93 reads (27%) | called by muse, mutect2, varscan2
- SLC66A1L | n.443+6298C>T | Intron (SNP) | VAF 48/348 reads (14%) | called by muse, mutect2, varscan2
- TMEM154 | c.*6925C>T | 3'UTR (SNP) | VAF 18/89 reads (20%) | called by muse, mutect2, varscan2
- TMEM199 | c.*1604C>A | 3'UTR (SNP) | VAF 6/45 reads (13%) | called by muse, varscan2
- TMEM199 | c.*1638C>G | 3'UTR (SNP) | VAF 6/44 reads (14%) | called by muse, varscan2
- TNFRSF10D | c.-41G>A | 5'UTR (SNP) | VAF 39/210 reads (19%) | called by muse, mutect2, varscan2
- TRMT9B | c.*43C>G | 3'UTR (SNP) | VAF 34/203 reads (17%) | catalogued as rs1243464422, COSV71600880; called by muse, varscan2
- TYRO3 | c.409+34T>A | Intron (SNP) | VAF 10/28 reads (36%) | called by muse, mutect2
- USP12 | c.*2029G>A | 3'UTR (SNP) | VAF 31/57 reads (54%) | called by muse, mutect2, varscan2
- ZNF148 | c.*600A>C | 3'UTR (SNP) | VAF 28/129 reads (22%) | called by muse, mutect2, varscan2
